Gene-level copy-number profile of tumor specimen AP-XSR5-HD from APOLLO case AP-XSR5, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-XSR5-HD: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cfa15b7e-11e1-4094-b0f3-f440e56a9a58.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-XSR5-LP (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/85ec398f-26f5-43a9-bc7f-7802258ecb6b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 959; copy number 2: 9,852; copy number 3: 7,796; copy number 4: 33,270; copy number 5: 4,026; copy number 6: 2,015; copy number 7: 439.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:118,712,999–118,713,678, 1 gene: AL139148.1.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr15:20,379,495–20,599,195, 7 genes: HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P.
- chr15:20,901,441–21,058,440, 6 genes (within-gene range 0–1): ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
